Somatic mutation profile of tumor specimen C3L-01124-01 (aliquot CPT0218200007) from CPTAC case C3L-01124, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 71.0 years (25,921 days).
Specimen C3L-01124-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 15dea1e8-ba9e-40b4-9abf-889955af6fa5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01124-31 (Blood Derived Normal), aliquot CPT0220240002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/25281f7a-bb05-43c0-9316-f5f7df2adc2d

The open-access MAF lists 30 somatic variants for this specimen: 18 protein-altering or splice-affecting, 8 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 8, Nonsense Mutation 2, Intron 2, 3'UTR 1, Splice Region 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 26/302 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- TP53 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 55/680 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs786201059, CM076567, CM1212545, COSV52664318, COSV52687201, COSV52688214; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- AP1M1 | c.646G>A p.D216N | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs1459508738; called by muse, mutect2
- ARHGEF28 | c.704G>A p.S235N | Missense Mutation (SNP) | VAF 7/142 reads (5%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV55266675; called by muse, mutect2
- DRGX | c.65G>A p.G22E | Missense Mutation (SNP) | VAF 16/352 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.05); catalogued as rs1164284285; called by muse, mutect2
- DROSHA | c.760C>T p.R254C | Missense Mutation (SNP) | VAF 13/181 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs761643386; called by muse, mutect2
- EXOC7 | c.1990G>A p.E664K (on ENST00000335146 / NM_001145297.4; = p.E582K on NM_015219.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1450898488; called by muse, mutect2, varscan2
- GAD1 | c.1591C>T p.R531* | Nonsense Mutation (SNP) | VAF 45/539 reads (8%) | catalogued as rs745595462; called by muse, mutect2
- MDGA2 | c.688G>T p.A230S | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.376); catalogued as COSV62077732; called by muse, mutect2
- RHPN2 | c.560C>T p.P187L | Missense Mutation (SNP) | VAF 39/606 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV99577425; called by muse, mutect2
- RIPOR1 | c.494G>A p.R165H (on ENST00000379312 / NM_001193522.2; = p.R161H on NM_024519.4) | Missense Mutation (SNP) | VAF 36/402 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs369864235; called by muse, mutect2
- SLC45A1 | c.109C>T p.R37* | Nonsense Mutation (SNP) | VAF 42/520 reads (8%) | catalogued as rs1251005483, COSV57096740; called by muse, mutect2
- TNN | c.3343C>T p.R1115W | Missense Mutation (SNP) | VAF 33/280 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs546877646, COSV53435922; called by muse, mutect2, varscan2
- TRABD | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 13/159 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs747329304; called by muse, mutect2
- ACVR1C | c.428A>G p.Y143C | Missense Mutation (SNP) | VAF 30/391 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.005); called by muse, mutect2
- SLC39A10 | c.773G>A p.G258D | Missense Mutation (SNP) | VAF 15/193 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2
- TMEM270 | c.501G>A p.K167= | Splice Region (SNP) | VAF 10/72 reads (14%) | called by mutect2, varscan2
- UBE2O | c.1171A>C p.K391Q | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.134); called by muse, mutect2
- GALNT17 | c.636C>T p.P212= | Silent (SNP) | VAF 14/90 reads (16%) | catalogued as rs371536707; called by muse, mutect2
- GTF2IRD2 | c.1785C>A p.I595= | Silent (SNP) | VAF 20/216 reads (9%) | catalogued as COSV63100034; called by muse, mutect2
- NELFCD | c.1038C>T p.F346= (on ENST00000602795; = p.F328= on NM_198976.4) | Silent (SNP) | VAF 19/275 reads (7%) | called by muse, mutect2
- NFASC | c.3564C>T p.D1188= (on ENST00000339876 / NM_001378329.1; = p.D1117= on NM_015090.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 24/322 reads (7%) | catalogued as rs765412087; called by muse, mutect2
- PRR23B | c.711G>A p.P237= | Silent (SNP) | VAF 7/171 reads (4%) | catalogued as rs1469437118, COSV100272157, COSV61494082; called by muse, mutect2
- PRR33 | c.243G>A p.P81= | Silent (SNP) | VAF 8/142 reads (6%) | catalogued as rs866562938; called by muse, mutect2
- SEMA3B | c.1548C>T p.C516= | Silent (SNP) | VAF 8/172 reads (5%) | called by muse, mutect2
- ZNF540 | c.645T>C p.C215= | Silent (SNP) | VAF 11/171 reads (6%) | called by muse, mutect2
- ADAMTS18 | c.-10G>T | 5'UTR (SNP) | VAF 25/276 reads (9%) | catalogued as rs1286791076; called by muse, mutect2
- ADD2 | c.1742-267A>G | Intron (SNP) | VAF 16/344 reads (5%) | catalogued as COSV100034836; called by muse, mutect2
- CCDC50 | c.*45T>C | 3'UTR (SNP) | VAF 27/204 reads (13%) | called by muse, mutect2, varscan2
- SCFD1 | c.613+602C>T | Intron (SNP) | VAF 22/248 reads (9%) | called by muse, mutect2
